Somatic mutation profile of tumor specimen TCGA-46-3765-01A (aliquot TCGA-46-3765-01A-01D-0983-08) from TCGA case TCGA-46-3765, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.6 years (21,762 days).
Specimen TCGA-46-3765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f0e219a-d4ef-46b3-a71f-ba302d92b715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-46-3765-10A (Blood Derived Normal), aliquot TCGA-46-3765-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95367914-2f45-40dc-b29d-1ec341841896

The open-access MAF lists 244 somatic variants for this specimen: 183 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 55, Nonsense Mutation 14, Splice Site 4, Frame Shift Del 4, Intron 3, RNA 2, Frame Shift Ins 1, 3'Flank 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 13/128 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960047; called by muse, mutect2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ADAM18 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564249507, COSV55852502; called by muse, mutect2, varscan2
- ADAM29 | c.2407C>T p.Q803* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs141115697, COSV63662395, COSV63665952; called by muse, varscan2
- AFP | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV56926548; called by muse, varscan2
- AIMP2 | c.207G>C p.L69F | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56151716; called by muse, mutect2, varscan2
- AKAP13 | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV63463010, COSV63466075; called by muse, mutect2, varscan2
- AKAP13 | c.3890C>T p.T1297I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); catalogued as rs1398417022, COSV63466080; called by muse, mutect2, varscan2
- ALMS1 | c.5227C>T p.Q1743* | Nonsense Mutation (SNP) | VAF 13/165 reads (8%) | catalogued as COSV52518366; called by muse, mutect2
- ANO3 | c.1517G>T p.W506L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV56803356; called by muse, mutect2, varscan2
- AOX1 | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV65983387; called by muse, mutect2, varscan2
- AP5Z1 | c.2408G>A p.G803D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV62243117; called by muse, mutect2, varscan2
- APOB | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51947324; called by muse, varscan2
- AREG | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 138/284 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1014706674, COSV52645097; called by muse, varscan2
- ARHGAP18 | c.1198G>C p.A400P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63765715; called by muse, mutect2, varscan2
- ARHGAP32 | c.5834C>T p.S1945F (on ENST00000310343 / NM_001378025.1; = p.S1596F on NM_014715.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV59853494; called by muse, mutect2, varscan2
- ASXL3 | c.3451A>G p.K1151E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52475361; called by muse, mutect2, varscan2
- ASXL3 | c.5859G>T p.K1953N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52475371; called by muse, varscan2
- ASXL3 | c.5923G>C p.V1975L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV52475384; called by muse, varscan2
- ATP6V1G3 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV55280339; called by muse, mutect2, varscan2
- ATRX | c.7464A>T p.Q2488H | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV64881294; called by muse, mutect2, varscan2
- ATXN7L2 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs759451895, COSV60205734; called by mutect2, varscan2
- AXDND1 | c.2891A>T p.E964V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62646684; called by mutect2, varscan2
- BBS7 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52658693; called by muse, mutect2, varscan2
- BOD1L1 | c.3700G>C p.D1234H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV50040560; called by muse, mutect2, varscan2
- BRIP1 | c.2164A>G p.T722A | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52006048; called by muse, mutect2, varscan2
- BRWD3 | c.4603G>T p.D1535Y | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV64752185; called by muse, mutect2, varscan2
- BTN2A2 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV61858222; called by muse, mutect2, varscan2
- C11orf49 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as rs14051, COSV53568768, COSV53569395; called by muse, mutect2, varscan2
- C5AR1 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100754087, COSV61893100; called by muse, mutect2, varscan2
- CADPS | c.3497T>C p.I1166T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as rs774478977, COSV51895733; called by muse, mutect2, varscan2
- CARD8 | c.296C>T p.P99L (on ENST00000651546 / NM_001184900.3; = p.P49L on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62874801; called by muse, mutect2, varscan2
- CASR | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56140331; called by muse, mutect2, varscan2
- CBLN2 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54052568; called by muse, mutect2, varscan2
- CCDC50 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV101165340, COSV66667102; called by muse, mutect2, varscan2
- CCM2 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV51850585; called by muse, mutect2, varscan2
- CD109 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137899447, COSV54647782; called by mutect2, varscan2
- CDH19 | c.2007G>C p.K669N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV50970558; called by muse, mutect2
- CDKN2A | c.293A>C p.H98P | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.647); catalogued as COSV58683927, COSV58696031; called by muse, varscan2
- CHAMP1 | c.1914A>T p.K638N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV63522952; called by muse, mutect2, varscan2
- CIC | c.1739G>C p.G580A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV50560375, COSV50645324; called by muse, mutect2, varscan2
- CLDN10 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV65296963; called by mutect2, varscan2
- CSAD | c.410C>T p.A137V (on ENST00000444623 / NM_001244705.2; = p.A164V on NM_015989.5) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57244391; called by muse, mutect2, varscan2
- CSMD3 | c.8908T>A p.F2970I (on ENST00000297405 / NM_001363185.1; = p.F2801I on NM_052900.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV52276814; called by mutect2, varscan2
- DCAF12L1 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV64422545; called by muse, mutect2, varscan2
- EIF2AK3 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs758957898, COSV57546690; called by muse, mutect2, varscan2
- FAT3 | c.5752C>G p.L1918V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); catalogued as rs1316245098, COSV53156987; called by muse, mutect2, varscan2
- FAT3 | c.6838G>T p.V2280L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV53157010; called by muse, mutect2, varscan2
- FBH1 | c.1852G>A p.E618K (on ENST00000362091 / NM_178150.3; = p.E669K on NM_032807.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.063); catalogued as COSV62984039; called by muse, mutect2, varscan2
- FBN3 | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54459671, COSV54469072; called by muse, mutect2, varscan2
- FCGR3A | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as COSV63460321; called by mutect2, varscan2
- FLG2 | c.3427C>G p.Q1143E | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV66171659; called by muse, mutect2, varscan2
- FLT1 | c.2320C>A p.L774I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.963); catalogued as rs1234107941, COSV56737634; called by muse, mutect2, varscan2
- FRY | c.886-2A>T p.X296_splice | Splice Site (SNP) | VAF 26/92 reads (28%) | catalogued as COSV66576442; called by muse, mutect2, varscan2
- GORASP2 | c.1169C>G p.T390S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.015); catalogued as COSV52203386; called by muse, mutect2, varscan2
- GPER1 | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52470221; called by muse, mutect2, varscan2
- HBP1 | c.1225T>A p.S409T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56018975; called by mutect2, varscan2
- HCN1 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV57493385, COSV57515422; called by muse, mutect2, varscan2
- HERC6 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV52033396; called by muse, mutect2, varscan2
- HHIPL2 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV58566906, COSV58567930; called by muse, mutect2, varscan2
- HIBCH | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62891742, COSV62892730; called by mutect2, varscan2
- HNF1A | c.1213A>T p.M405L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV57465779, COSV57468175; called by muse, mutect2, varscan2
- IARS2 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV56962814, COSV56963514; called by muse, mutect2, varscan2
- IKBIP | c.1034A>G p.H345R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as COSV61082458; called by muse, mutect2, varscan2
- IMP4 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52092477; called by muse, mutect2, varscan2
- ITGA5 | c.2938C>A p.R980S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV53215090, COSV53219955; called by muse, mutect2, varscan2
- JAKMIP2 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1348606788, COSV54612336, COSV54615149; called by muse, mutect2, varscan2
- KCNA3 | c.1162G>C p.G388R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63902385; called by muse, mutect2, varscan2
- KCTD7 | c.578C>G p.S193C (on ENST00000275532; = p.L206= on NM_153033.5) | Missense Mutation (SNP) | VAF 268/300 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as rs930655842, COSV51877349; called by muse, mutect2, varscan2
- KIAA1109 | c.10924G>A p.E3642K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV52687083; called by mutect2, varscan2
- KLF8 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV63848530; called by muse, mutect2, varscan2
- KLHL1 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.012); catalogued as COSV64779172; called by muse, mutect2, varscan2
- LAX1 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV65849910; called by muse, mutect2, varscan2
- LCOR | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as COSV63629793, COSV63631962; called by muse, mutect2, varscan2
- LDB2 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58778012; called by muse, mutect2, varscan2
- LMBR1L | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV57202721; called by muse, mutect2, varscan2
- LPA | c.3966C>A p.Y1322* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV60307966; called by muse, varscan2
- LRP1B | c.12385T>A p.Y4129N | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67258930, COSV67277919; called by muse, mutect2, varscan2
- LRRC49 | c.1520A>G p.N507S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs745593629, COSV53014135; called by muse, mutect2, varscan2
- MAP2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV52303349; called by muse, mutect2, varscan2
- MAP3K21 | c.1352T>G p.L451R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV64045934; called by muse, mutect2, varscan2
- MARCHF10 | c.1583A>G p.H528R | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV60889759; called by muse, mutect2, varscan2
- MEGF10 | c.776G>T p.W259L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV57254493; called by muse, varscan2
- MEGF10 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57254499; called by muse, mutect2, varscan2
- MKRN3 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as CM148547, COSV58809140, COSV58811519; called by muse, mutect2, varscan2
- NAV3 | c.1385T>A p.L462* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as COSV57103335; called by muse, mutect2, varscan2
- NDNF | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as COSV65632655; called by muse, mutect2, varscan2
- NEBL | c.1999G>T p.V667L | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.791); catalogued as COSV65805071; called by muse, mutect2, varscan2
- NID2 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs779010790, COSV53493702, COSV53500989; called by muse, mutect2, varscan2
- NIPBL | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV56961476; called by muse, mutect2, varscan2
- NLRP12 | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100145940, COSV60752478; called by muse, mutect2, varscan2
- NPBWR2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.723); catalogued as rs373389160, COSV63900157; called by muse, mutect2, varscan2
- OR14J1 | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV65845892; called by muse, mutect2, varscan2
- OR2L13 | c.422T>A p.V141E | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV63558581; called by muse, mutect2, varscan2
- OR2M3 | c.738G>T p.L246F | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV71758974; called by muse, mutect2, varscan2
- OR2T27 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as rs766705132, COSV61283135; called by muse, mutect2, varscan2
- OR4D9 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61435145; called by muse, mutect2, varscan2
- OR51B2 | c.251G>T p.W84L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100173469; called by muse, mutect2, varscan2
- OR5D14 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as rs749031307, COSV59457872; called by muse, mutect2, varscan2
- OR5D18 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs371559921; called by muse, mutect2, varscan2
- OR6B1 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68770480; called by muse, mutect2, varscan2
- PABPC3 | c.42C>G p.Y14* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV55797176, COSV55798143; called by muse, mutect2, varscan2
- PACSIN1 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV55061892; called by muse, mutect2, varscan2
- PCDHA12 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782463342, COSV56534458; called by muse, mutect2, varscan2
- PCDHA3 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV65370101; called by muse, mutect2, varscan2
- PDS5B | c.3967G>T p.A1323S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV59732205; called by muse, mutect2, varscan2
- PEAK1 | c.2825A>T p.D942V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV56941095; called by muse, mutect2, varscan2
- PEG3 | c.1506del p.K503Nfs*76 | Frame Shift Del (DEL) | VAF 32/153 reads (21%) | catalogued as COSV99690080; called by mutect2, pindel, varscan2
- PEG3 | c.1071G>T p.R357S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV55641077, COSV55643391; called by muse, mutect2, varscan2
- PLEKHO1 | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs782606986, COSV50311064; called by muse, mutect2, varscan2
- POTEH | c.480C>A p.Y160* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | catalogued as COSV100625161, COSV58880197; called by muse, mutect2, varscan2
- PREX2 | c.2248A>T p.K750* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV55793069; called by muse, mutect2
- PSMB4 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs768718256, COSV51852803; called by muse, varscan2
- PSMC4 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as COSV50097092; called by mutect2, varscan2
- PTK2 | c.2753A>G p.D918G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61790344; called by muse, mutect2, varscan2
- PTPN21 | c.2407A>T p.T803S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as COSV60850979; called by muse, varscan2
- PTPRB | c.5518G>A p.E1840K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54249820; called by muse, mutect2, varscan2
- RAPGEF1 | c.2080G>C p.G694R | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV64701460; called by muse, mutect2, varscan2
- RBSN | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1375580926, COSV53793133, COSV99037602; called by muse, mutect2, varscan2
- RECK | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV65036068; called by muse, mutect2, varscan2
- RGS7 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV58555367; called by muse, mutect2, varscan2
- RNF213 | c.12952C>A p.Q4318K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60405859; called by muse, mutect2, varscan2
- SCD | c.1060G>C p.G354R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV64853467; called by muse, mutect2, varscan2
- SCD | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64853469; called by muse, mutect2, varscan2
- SH3RF2 | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV63037508, COSV63040715; called by muse, mutect2, varscan2
- SHISA2 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60110108; called by muse, mutect2, varscan2
- SLC22A16 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as rs749775428, COSV57931395; called by muse, mutect2, varscan2
- SLC25A16 | c.461T>A p.V154D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56265893; called by muse, mutect2, varscan2
- SLC2A13 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.065); catalogued as COSV55117416; called by muse, mutect2, varscan2
- SLC45A2 | c.1291T>C p.F431L | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV56874416, COSV99672925; called by muse, varscan2
- SLC5A9 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV52585067; called by muse, mutect2, varscan2
- SLC6A8 | c.1371C>G p.I457M | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV53473058; called by muse, mutect2, varscan2
- SOAT2 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs760362737, COSV56860727; called by muse, mutect2, varscan2
- SORBS2 | c.1151G>T p.C384F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52990618; called by muse, mutect2, varscan2
- SORL1 | c.4054G>C p.D1352H | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52760163, COSV52763324; called by muse, mutect2, varscan2
- STS | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs200993070, COSV54266849; called by muse, mutect2, varscan2
- STX1B | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV53061881; called by muse, mutect2, varscan2
- SUCLG2 | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV56210412; called by muse, mutect2, varscan2
- SYNE1 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 18/66 reads (27%) | catalogued as rs1440276153, COSV55065296; called by muse, mutect2, varscan2
- SYNGAP1 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.626); catalogued as rs557096495, COSV53381373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDRD7 | c.1703G>A p.C568Y | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777562034, COSV62430655; called by muse, mutect2, varscan2
- TGM5 | c.1611G>T p.K537N (on ENST00000220420 / NM_201631.4; = p.K455N on NM_004245.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV55010381, COSV55011603; called by muse, mutect2, varscan2
- TKTL2 | c.1673G>C p.G558A | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV54920684; called by muse, mutect2, varscan2
- TKTL2 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV54920696; called by muse, mutect2, varscan2
- TMEM106C | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV56743357; called by muse, varscan2
- TPBG | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV63882970; called by muse, mutect2, varscan2
- TPCN2 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV53732809; called by muse, mutect2, varscan2
- TRHR | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61234023; called by muse, mutect2, varscan2
- TRPC4AP | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV52683128; called by muse, mutect2, varscan2
- TTLL6 | c.2401A>G p.N801D (on ENST00000393382 / NM_001130918.3; = p.N494D on NM_173623.3) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV64976775, COSV64978617; called by muse, mutect2, varscan2
- TTN | c.66982G>T p.G22328* (on ENST00000591111; = p.G14904* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | catalogued as COSV100633729, COSV60258403; called by muse, mutect2, varscan2
- TTN | c.12139G>A p.V4047M (on ENST00000591111; = p.V4001M on NM_003319.4) | Missense Mutation (SNP) | VAF 32/217 reads (15%) | catalogued as rs201506104; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TWIST1 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM056999, CM980021, COSV54251320; called by muse, mutect2, varscan2
- TXLNG | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV66330357; called by muse, mutect2, varscan2
- UNC5D | c.1997G>T p.C666F | Missense Mutation (SNP) | VAF 167/237 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54823064; called by muse, mutect2, varscan2
- UNC5D | c.2375T>C p.L792P | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54823083; called by muse, mutect2, varscan2
- USE1 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.683); catalogued as COSV55728597, COSV55728791; called by muse, varscan2
- USP24 | c.4711C>T p.R1571C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs201975935, COSV53775289; called by muse, mutect2, varscan2
- USP29 | c.1469A>C p.K490T | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV54140041, COSV54145541; called by muse, mutect2, varscan2
- USP32 | c.2538A>C p.E846D | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100342610; called by muse, mutect2
- USP35 | c.2452A>T p.M818L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1246873774, COSV60870171; called by muse, mutect2, varscan2
- VCAN | c.9716G>C p.W3239S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54099874, COSV54113450, COSV99424268; called by muse, mutect2, varscan2
- VPS26B | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392483854, COSV55544213, COSV99844832; called by muse, mutect2
- VPS50 | c.1539G>T p.L513F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.979); catalogued as COSV58510201; called by muse, mutect2, varscan2
- WDR7 | c.2687C>G p.S896C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54348968, COSV54360508; called by muse, mutect2, varscan2
- WRN | c.3939G>C p.Q1313H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV53305156; called by muse, mutect2, varscan2
- XAB2 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372303491, COSV64322294; called by muse, mutect2
- ZNF471 | c.1799A>T p.Q600L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57292873; called by muse, mutect2, varscan2
- ZNF536 | c.-1G>A | Splice Region (SNP) | VAF 22/98 reads (22%) | catalogued as COSV100835636; called by muse, varscan2
- ZNF560 | c.1155C>A p.F385L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1360289040, COSV100038905; called by muse, mutect2, varscan2
- ZNF618 | c.2483A>T p.K828M (on ENST00000374126 / NM_001318042.2; = p.K735M on NM_133374.2) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV55927225; called by muse, mutect2, varscan2
- ZNF761 | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.234); catalogued as COSV61889089; called by muse, mutect2, varscan2
- ZNF91 | c.1550C>G p.P517R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56090320; called by muse, mutect2, varscan2
- ZNF91 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 17/89 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV56090337; called by muse, mutect2, varscan2
- ZXDA | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62388510, COSV62388547; called by muse, mutect2, varscan2
- CUX2 | c.1901del p.X634_splice | Splice Site (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel
- HOXB3 | c.169del p.L57Wfs*18 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.1108-2A>G p.X370_splice | Splice Site (SNP) | VAF 48/221 reads (22%) | called by muse, mutect2, varscan2
- PPM1F | c.367del p.Q123Kfs*67 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- RAB3GAP2 | c.4062dup p.A1355Cfs*5 | Frame Shift Ins (INS) | VAF 45/172 reads (26%) | called by mutect2, pindel, varscan2
- SLC18A3 | c.1052_1053del p.R351Lfs*98 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by pindel, varscan2
- SLC19A1 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- SPATA31A3 | c.2130G>T p.R710S | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by mutect2, varscan2
- ATP6V0A4 | c.1356C>T p.I452= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV59479032; called by muse, mutect2, varscan2
- BEX1 | c.267G>A p.V89= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as rs1228544763, COSV65580520; called by muse, mutect2, varscan2
- BICD1 | c.2364C>G p.L788= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55685488; called by muse, mutect2, varscan2
- BLZF1 | c.1023A>G p.L341= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV61394549; called by muse, mutect2
- CCDC150 | c.1341G>A p.E447= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV55877361; called by muse, mutect2, varscan2
- CDH13 | c.724C>A p.R242= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs751441653, COSV51813549, COSV99224247; called by muse, mutect2, varscan2
- CPNE5 | c.1026C>T p.P342= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV55198906; called by muse, mutect2, varscan2
- DMAC1 | c.102G>T p.A34= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV64066006; called by muse, mutect2, varscan2
- EPHA3 | c.2739C>T p.F913= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV60720477; called by muse, mutect2, varscan2
- FCRL1 | c.927C>A p.V309= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV63826749, COSV63827172; called by muse, mutect2, varscan2
- FLG | c.11217C>T p.H3739= | Silent (SNP) | VAF 103/268 reads (38%) | catalogued as rs774213318, COSV64244306; called by muse, mutect2, varscan2
- FSIP2 | c.18828T>C p.G6276= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100555963; called by muse, varscan2
- GBP2 | c.888G>A p.L296= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV65070106; called by muse, mutect2, varscan2
- GLDN | c.522T>C p.N174= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV59091784; called by muse, mutect2, varscan2
- GLYR1 | c.708G>A p.T236= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1191186005, COSV58928623; called by muse, mutect2, varscan2
- GXYLT2 | c.525C>T p.I175= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as COSV67474879; called by muse, mutect2, varscan2
- HELB | c.2967C>T p.V989= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56075447; called by mutect2, varscan2
- IQGAP3 | c.3765G>A p.Q1255= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV63253767; called by muse, mutect2, varscan2
- IQUB | c.1479C>T p.I493= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV61241673; called by muse, mutect2, varscan2
- KAT6A | c.1953T>G p.P651= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV55910624; called by muse, varscan2
- KRTAP1-3 | c.159T>C p.S53= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV60336845; called by muse, varscan2
- LYPD4 | c.342C>T p.L114= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV58028105, COSV58028270; called by muse, varscan2
- MUC16 | c.16719G>A p.G5573= | Silent (SNP) | VAF 15/208 reads (7%) | catalogued as COSV67484032; called by muse, mutect2
- NFE2L1 | c.1014T>C p.S338= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV62583681; called by muse, mutect2, varscan2
- NGFR | c.453C>T p.D151= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1045395377, COSV50803651, COSV50803962; called by muse, mutect2, varscan2
- NLRP10 | c.1407C>T p.F469= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV60781839; called by muse, mutect2, varscan2
- NLRP3 | c.1995C>A p.S665= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs1408989747, COSV60229527; called by mutect2, varscan2
- NPC1L1 | c.3420C>G p.L1140= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV56928928; called by muse, mutect2, varscan2
- OLAH | c.537C>T p.I179= (on ENST00000378228 / NM_001039702.3; = p.I232= on NM_018324.3) | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV65493824; called by mutect2, varscan2
- OR4A15 | c.912A>C p.V304= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV59036920; called by muse, mutect2, varscan2
- PCARE | c.1125A>G p.P375= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs748685996, COSV59056886; called by muse, mutect2, varscan2
- PFKFB3 | c.972C>T p.I324= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs757703975, COSV57992022; called by mutect2, varscan2
- PLCL1 | c.612T>G p.V204= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV70862106; called by muse, mutect2, varscan2
- PNLIP | c.1239G>A p.Q413= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV65041650; called by muse, mutect2, varscan2
- PREX2 | c.2247G>T p.T749= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV55793051, COSV55794630; called by muse, mutect2
- PXDNL | c.564G>A p.L188= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100683361, COSV62495573; called by muse, mutect2, varscan2
- RASA3 | c.1251G>A p.L417= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV61871726, COSV61874423; called by mutect2, varscan2
- RGS7 | c.1317A>T p.I439= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV58555357; called by muse, mutect2, varscan2
- RHOT2 | c.1779G>T p.G593= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV54809954; called by muse, varscan2
- RNF213 | c.13851G>A p.Q4617= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100300009, COSV60405874; called by muse, mutect2, varscan2
- SLC9A5 | c.255G>A p.L85= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV50766363; called by muse, mutect2, varscan2
- SORT1 | c.1161C>T p.S387= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1454781041, COSV56668924; called by muse, mutect2, varscan2
- STK26 | c.1050G>C p.L350= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV53748118; called by muse, mutect2, varscan2
- SYT13 | c.750C>T p.S250= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs754348148, COSV50076018; called by muse, mutect2, varscan2
- TLR7 | c.2214G>A p.L738= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV66125166; called by muse, mutect2, varscan2
- TONSL | c.615C>G p.R205= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV68049067; called by muse, mutect2, varscan2
- TTN | c.85722C>A p.V28574= (on ENST00000591111; = p.V21150= on NM_003319.4) | Silent (SNP) | VAF 24/280 reads (9%) | catalogued as COSV60258360; called by muse, mutect2
- UNC79 | c.1656G>A p.L552= (on ENST00000393151 / NM_001346218.2; = p.L375= on NM_020818.5) | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV56376935; called by muse, mutect2, varscan2
- USE1 | c.270G>T p.L90= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV55728584; called by muse, varscan2
- VPREB1 | c.129G>A p.L43= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs748929156, COSV56426156; called by mutect2, varscan2
- VSIR | c.261G>A p.R87= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV56482112; called by muse, mutect2, varscan2
- XPO5 | c.750C>A p.L250= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV54833704; called by muse, mutect2, varscan2
- ZIK1 | c.96C>A p.I32= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV56738156; called by muse, mutect2, varscan2
- ZNF292 | c.4128C>A p.I1376= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV60544697; called by muse, mutect2, varscan2
- ZNF99 | c.1914A>G p.K638= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV68056341; called by muse, varscan2
- CWF19L1 | c.1255-226T>C | Intron (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100821612; called by muse, mutect2, varscan2
- IGKV1-13 | n.269G>T | RNA (SNP) | VAF 58/277 reads (21%) | called by muse, varscan2
- IGLV8OR8-1 | n.65T>C | RNA (SNP) | VAF 11/48 reads (23%) | called by muse, varscan2
- RN7SL484P | chr15:99792214 C>A | 3'Flank (SNP) | VAF 27/116 reads (23%) | called by muse, mutect2, varscan2
- RNF216 | c.202-50G>C | Intron (SNP) | VAF 30/144 reads (21%) | catalogued as COSV101111364; called by muse, mutect2, varscan2
- TTN | c.10360+3560G>T | Intron (SNP) | VAF 24/127 reads (19%) | catalogued as COSV60258489; called by muse, mutect2, varscan2
